Somatic mutation profile of tumor specimen 0DUUQ3 from CCDI case PBCLUI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 10.7 years (3,894 days).
Specimen 0DUUQ3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0266571-198c-491a-bfff-5cf443014dc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUUPP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a610c30-ce4f-4c22-ab6d-7fbea900ab61

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.2392C>A p.Q798K | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV57656291; called by muse, varscan2
- SLAMF1 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 96/206 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs1332843058; called by muse, varscan2
- SLC12A3 | c.2329C>T p.R777W | Missense Mutation (SNP) | VAF 107/239 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs748994629; called by muse, varscan2
- SLC44A2 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs1202831048; called by muse, varscan2
- TMPRSS15 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 115/411 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs774868000, COSV53039422; called by muse, varscan2
- TMEM100 | c.219G>A p.A73= | Silent (SNP) | VAF 154/358 reads (43%) | catalogued as rs570453335; called by muse, varscan2
- ASB6 | c.295+29T>G | Intron (SNP) | VAF 7/52 reads (13%) | called by muse, varscan2
